Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6473, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6473-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) HYPOPHARYNX, LEFT, EXCISION: DIFFUSELY INVOLVED BY INVASIVE MODERATELY TO POORLY DIFFERENTIATED PAPILLARY SQUAMOUS CELL CARCINOMA.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Left pharyngeal mass

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)hypopharyngeal mass

GROSS DESCRIPTION:

1) SOURCE: Left Hypopharyngeal Mass

Received fresh are multiple fragments of unoriented tissue measuring 8.0 x 7.0 x 2.0 cm. The specimens range from white-tan and exophytic to brown-red portions of soft tissue. No obvious surgical resection margins or oriented planes of resection can be identified. Therefore, no portion of the specimen is inked. Representative sections of the specimens are submitted. Summary of sections: 1A, 1B, 2/1 each; 1C-1F, 1/1 each.

Dictated by [REDACTED]
Slides and report reviewed by Attending Pathologist.

[REDACTED] Release of Information [REDACTED]

Source: NCI Genomic Data Commons file cf177a82-f975-410f-a8ad-d5ab5194c8b3 (TCGA-CR-6473.681B2A65-E06E-4AF1-BCBB-02E21C693FB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).